Gene-level copy-number profile of tumor specimen ALCH-B0BR-TTP1-A from ALCHEMIST case ALCH-B0BR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.5 years (23,918 days).
Specimen ALCH-B0BR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8c763554-9dbc-4724-8469-be0c8869937a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0BR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/bd802ec1-d0df-4b8c-880d-9132c2f5efb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 6,132; copy number 2: 45,963; copy number 3: 5,914; copy number 4: 726; copy number 5: 168.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 168 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,881,236–151,953,985, 71 genes, copy number 5 (broad region; genes not listed).
- chr1:155,255,979–157,045,742, 94 genes, copy number 5 (broad region; genes not listed).
- chr16:32,600,299–32,615,639, 1 gene, copy number 5: AC137800.1.
- chr21:10,640,028–10,649,835, 2 genes, copy number 5: AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 3,295. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
